Somatic mutation profile of tumor specimen TCGA-BR-A452-01A (aliquot TCGA-BR-A452-01A-91D-A25D-08) from TCGA case TCGA-BR-A452, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 57.8 years (21,107 days).
Specimen TCGA-BR-A452-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a8a4817-a32b-4bf3-bab5-08a8d801e2b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-A452-10A (Blood Derived Normal), aliquot TCGA-BR-A452-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f073df9-e5e0-4628-9e22-11a499d0e5b5

The open-access MAF lists 118 somatic variants for this specimen: 82 protein-altering or splice-affecting, 35 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 70, Silent 35, Nonsense Mutation 4, Frame Shift Del 3, Splice Site 2, Frame Shift Ins 2, Nonstop Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LCE1A | c.83A>C p.K28T | Missense Mutation (SNP) | VAF 33/137 reads (24%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV58726434, COSV58726966, COSV58727394; called by muse, mutect2, varscan2
- PNLIPRP3 | c.1292A>C p.K431T | Missense Mutation (SNP) | VAF 18/61 reads (30%) | hotspot (GDC flag); SIFT tolerated (0.2); PolyPhen benign (0.241); catalogued as COSV65046911, COSV65048763; called by muse, mutect2, varscan2
- TP53 | c.527G>T p.C176F | Missense Mutation (SNP) | VAF 39/71 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRG1 | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 62/203 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.332); catalogued as rs770388074, COSV65635174; called by muse, mutect2, varscan2
- ANAPC15 | c.332G>A p.G111D | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV56190734; called by muse, varscan2
- AP002512.3 | c.89T>C p.L30P | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV56565679; called by muse, mutect2, varscan2
- APC | c.531+2T>G p.X177_splice | Splice Site (SNP) | VAF 17/37 reads (46%) | catalogued as CS106642, COSV57324309; called by muse, mutect2, varscan2
- ARHGEF26 | c.1205A>C p.K402T | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV62843780; called by muse, mutect2, varscan2
- ASTN1 | c.1433A>G p.E478G | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as COSV56061315; called by muse, mutect2, varscan2
- BDNF | c.87A>C p.Q29H | Missense Mutation (SNP) | VAF 54/130 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV59233135, COSV59239175; called by muse, mutect2, varscan2
- C2CD3 | c.1408G>A p.D470N | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.122); catalogued as COSV58089448; called by muse, mutect2, varscan2
- CCT8L2 | c.826C>A p.Q276K | Missense Mutation (SNP) | VAF 40/168 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.029); catalogued as COSV63461625, COSV63463818; called by muse, mutect2, varscan2
- CEP63 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV59674335; called by muse, mutect2, varscan2
- CHML | c.1364C>G p.S455C | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59362429; called by muse, mutect2, varscan2
- CNGB3 | c.2153A>G p.D718G | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1209870012, COSV60684573; called by muse, mutect2, varscan2
- COL1A2 | c.2992C>G p.P998A | Missense Mutation (SNP) | VAF 6/97 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51952768; called by muse, mutect2
- COL24A1 | c.4357G>A p.G1453S | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs766320753, COSV65301668; called by muse, mutect2, varscan2
- CSMD3 | c.778G>C p.E260Q | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.601); catalogued as COSV52101454, COSV52214304; called by muse, mutect2, varscan2
- DCSTAMP | c.524T>C p.L175P | Missense Mutation (SNP) | VAF 54/153 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV52576028, COSV52577809; called by muse, mutect2, varscan2
- DMD | c.8708T>G p.L2903R | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.438); catalogued as COSV58891237; called by muse, mutect2, varscan2
- FAT3 | c.1699C>T p.R567* | Nonsense Mutation (SNP) | VAF 16/56 reads (29%) | catalogued as rs1230731830, COSV53074844; called by muse, mutect2, varscan2
- FKTN | c.165+1G>A p.X55_splice | Splice Site (SNP) | VAF 12/38 reads (32%) | catalogued as rs774922597, COSV56308026; called by muse, mutect2, varscan2
- G3BP1 | c.869C>G p.S290C | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.436); catalogued as COSV62365506; called by muse, mutect2, varscan2
- GNB3 | c.687C>G p.I229M | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV51830906; called by muse, mutect2, varscan2
- GRAMD1C | c.416G>T p.R139L | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV100822768, COSV63981814; called by muse, mutect2, varscan2
- GTPBP3 | c.928G>A p.G310S | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0.03); catalogued as rs1348235536, COSV50173033; called by muse, mutect2
- GZMK | c.419A>C p.K140T | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.096); catalogued as COSV50244144; called by muse, mutect2, varscan2
- IGKV1-5 | c.345T>G p.S115R | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as rs772902986; called by muse, mutect2, varscan2
- IMPG1 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV64054177; called by muse, mutect2, varscan2
- ITGA10 | c.2624G>A p.R875Q | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.023); catalogued as rs781984123, COSV65195989; called by muse, mutect2, varscan2
- KCNT2 | c.1730C>T p.S577L | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs140538298; called by muse, mutect2, varscan2
- KNL1 | c.2425G>C p.G809R (on ENST00000346991 / NM_170589.5; = p.G783R on NM_144508.5) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.592); catalogued as COSV61150986, COSV61153413; called by mutect2, varscan2
- LAMA4 | c.3575T>G p.L1192R (on ENST00000230538 / NM_001105206.3; = p.L1185R on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV57891884, COSV57899342; called by muse, mutect2, varscan2
- LAMB4 | c.3052A>G p.T1018A | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as COSV52713186; called by muse, mutect2, varscan2
- LIN7A | c.224C>T p.T75M | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs747194295, COSV54017859; called by muse, mutect2, varscan2
- LUC7L | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.024); catalogued as rs747514409, COSV53456776; called by muse, mutect2, varscan2
- MIA2 | c.904C>T p.P302S | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.155); catalogued as COSV54482017, COSV54486973; called by muse, mutect2, varscan2
- NCAM2 | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53055967; called by muse, mutect2, varscan2
- NELL1 | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as rs1293915290, COSV54238607, COSV54314615; called by muse, mutect2, varscan2
- NLGN4X | c.918C>A p.C306* | Nonsense Mutation (SNP) | VAF 22/111 reads (20%) | catalogued as COSV52004211, COSV52005617; called by muse, mutect2, varscan2
- ODF2 | c.2359G>A p.E787K (on ENST00000434106 / NM_153433.2; = p.E763K on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as rs747309665, COSV59406224; called by muse, mutect2, varscan2
- OR2T6 | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.376); catalogued as rs750710520, COSV63215692; called by muse, mutect2, varscan2
- OR51A7 | c.371T>G p.L124R | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as COSV63787997, COSV63788424; called by muse, mutect2, varscan2
- PARP3 | c.1361C>T p.T454M | Missense Mutation (SNP) | VAF 28/218 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs199676447, COSV67168098; called by muse, mutect2, varscan2
- PAX3 | c.200T>C p.I67T | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as COSV51336904; called by muse, mutect2, varscan2
- PCLO | c.12608T>G p.F4203C | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1379507225, COSV61615646; called by muse, mutect2, varscan2
- PDIA4 | c.1286G>C p.R429T (on ENST00000286091 / NM_001371244.1; = p.R428T on NM_004911.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.278); catalogued as COSV53723384; called by muse, mutect2, varscan2
- PELI3 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.305); catalogued as rs760025197, COSV57856031; called by muse, mutect2, varscan2
- PER2 | c.2818G>C p.E940Q | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.97); PolyPhen benign (0.015); catalogued as COSV54521352; called by muse, mutect2, varscan2
- POM121L12 | c.886T>C p.S296P | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.808); catalogued as rs748665796, COSV68692201, COSV68692623; called by muse, mutect2, varscan2
- POMGNT2 | c.1409G>A p.G470E | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.78); PolyPhen benign (0.112); catalogued as COSV60952607; called by muse, mutect2, varscan2
- PZP | c.2759A>C p.K920T | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV54354333; called by muse, mutect2, varscan2
- RNF40 | c.1442G>A p.R481H | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV61213608, COSV61216053; called by muse, mutect2, varscan2
- RP1L1 | c.6541G>C p.E2181Q | Missense Mutation (SNP) | VAF 131/299 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.334); catalogued as COSV66751599; called by muse, mutect2, varscan2
- SEPTIN5 | c.740T>C p.I247T | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1364430204, COSV63530349; called by muse, mutect2, varscan2
- SPATA31D1 | c.3628T>G p.L1210V | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.237); catalogued as COSV61192705; called by muse, mutect2, varscan2
- STAP2 | c.967G>T p.E323* | Nonsense Mutation (SNP) | VAF 45/130 reads (35%) | catalogued as COSV55694473; called by muse, mutect2, varscan2
- SYNE1 | c.1337T>G p.L446R (on ENST00000367255 / NM_182961.4; = p.L453R on NM_033071.3) | Missense Mutation (SNP) | VAF 85/252 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as COSV54904935, COSV99551663; called by muse, mutect2, varscan2
- SYNGR4 | c.581C>T p.S194F | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.311); catalogued as COSV100785134, COSV61225069; called by muse, mutect2, varscan2
- THBS2 | c.2783G>A p.R928Q | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as rs566007634, COSV100828065, COSV64677019; called by muse, mutect2, varscan2
- TMEM200A | c.1066T>A p.S356T | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.64); PolyPhen benign (0.015); catalogued as COSV51649084; called by muse, mutect2, varscan2
- TONSL | c.976G>C p.D326H | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.956); catalogued as COSV68047575; called by muse, mutect2, varscan2
- TRPM6 | c.5975C>A p.S1992Y | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.459); catalogued as COSV62513022; called by muse, mutect2
- TTN | c.59617G>C p.A19873P (on ENST00000591111; = p.A12449P on NM_003319.4) | Missense Mutation (SNP) | VAF 46/210 reads (22%) | PolyPhen possibly damaging (0.837); catalogued as COSV59883974; called by muse, mutect2, varscan2
- TTN | c.16990C>A p.L5664M (on ENST00000591111; = p.L4737M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/78 reads (36%) | PolyPhen probably damaging (0.976); catalogued as COSV59884006; called by muse, varscan2
- TTN | c.9377A>C p.K3126T (on ENST00000591111; = p.K3080T on NM_003319.4) | Missense Mutation (SNP) | VAF 19/67 reads (28%) | PolyPhen benign (0.003); catalogued as COSV59884013; called by muse, mutect2, varscan2
- UHRF1 | c.1414C>G p.H472D (on ENST00000612630 / NM_001290050.1; = p.H485D on NM_013282.4) | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1378953622, COSV53573206; called by muse, mutect2, varscan2
- USP37 | c.2153G>C p.R718T | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.131); catalogued as COSV51441248; called by muse, mutect2, varscan2
- USP38 | c.102C>G p.D34E | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as rs762641102, COSV61024802; called by muse, mutect2, varscan2
- VEGFD | c.920T>C p.F307S | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52908847; called by muse, mutect2, varscan2
- WDCP | c.2165G>C p.*722Sext*21 | Nonstop Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as COSV54591434; called by muse, mutect2, varscan2
- WDFY3 | c.6398C>T p.P2133L | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); catalogued as COSV55693278, COSV99078509; called by muse, mutect2, varscan2
- ZCWPW2 | c.801A>C p.E267D | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV67497401; called by muse, mutect2, varscan2
- ZNF214 | c.403A>C p.N135H | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.204); catalogued as COSV53480536; called by muse, mutect2, varscan2
- ZNF358 | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 63/197 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); catalogued as COSV51173895; called by muse, mutect2, varscan2
- ZNF429 | c.331T>G p.L111V | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV61914402; called by muse, varscan2
- ZWINT | c.25G>T p.E9* | Nonsense Mutation (SNP) | VAF 10/40 reads (25%) | catalogued as COSV59184823; called by muse, mutect2
- BRWD1 | c.1058dup p.L353Ffs*4 | Frame Shift Ins (INS) | VAF 19/43 reads (44%) | called by mutect2, pindel, varscan2
- DNAH3 | c.6894dup p.C2299Mfs*8 | Frame Shift Ins (INS) | VAF 30/80 reads (38%) | called by mutect2, pindel, varscan2
- RB1 | c.811_814del p.T271Efs*14 | Frame Shift Del (DEL) | VAF 28/70 reads (40%) | called by mutect2, pindel, varscan2
- RBM45 | c.306del p.F102Lfs*25 | Frame Shift Del (DEL) | VAF 13/69 reads (19%) | called by mutect2, pindel, varscan2
- SNRNP70 | c.147+1del | Frame Shift Del (DEL) | VAF 73/263 reads (28%) | called by mutect2, pindel, varscan2
- ACKR3 | c.789C>G p.V263= | Silent (SNP) | VAF 46/160 reads (29%) | catalogued as COSV56020495; called by muse, mutect2, varscan2
- APOB | c.12285C>T p.L4095= | Silent (SNP) | VAF 26/110 reads (24%) | catalogued as rs749245462, COSV51922945; called by muse, mutect2, varscan2
- C8orf34 | c.1185T>G p.T395= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV57397098; called by muse, mutect2, varscan2
- CDRT15 | c.135C>T p.I45= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs1205299212, COSV101415141; called by muse, mutect2, varscan2
- COL8A1 | c.2234A>G p.*745= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV53729297; called by muse, mutect2, varscan2
- CSE1L | c.2841G>A p.V947= | Silent (SNP) | VAF 28/92 reads (30%) | catalogued as COSV53700354; called by muse, mutect2, varscan2
- EPPK1 | c.5583C>T p.N1861= | Silent (SNP) | VAF 15/163 reads (9%) | catalogued as COSV73260796; called by muse, mutect2
- F13A1 | c.12T>G p.T4= | Silent (SNP) | VAF 28/114 reads (25%) | catalogued as COSV53553261; called by muse, mutect2, varscan2
- FAM50B | c.714C>T p.I238= | Silent (SNP) | VAF 28/78 reads (36%) | catalogued as COSV66654457; called by muse, mutect2, varscan2
- GAS2L2 | c.2388C>T p.P796= | Silent (SNP) | VAF 8/150 reads (5%) | catalogued as rs782821067; called by muse, mutect2
- KRTAP9-8 | c.75C>G p.T25= | Silent (SNP) | VAF 65/153 reads (42%) | catalogued as COSV54199343; called by muse, mutect2, varscan2
- LRRC7 | c.2376T>C p.R792= (on ENST00000651989 / NM_001370785.2; = p.R759= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 22/146 reads (15%) | catalogued as COSV50410483; called by muse, mutect2, varscan2
- MDH2 | c.414C>T p.C138= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as rs781887995, COSV59883696; called by muse, mutect2, varscan2
- MUC5B | c.11259G>A p.V3753= | Silent (SNP) | VAF 30/151 reads (20%) | catalogued as rs761584395, COSV101500121; called by muse, mutect2, varscan2
- OBSCN | c.3309G>A p.T1103= | Silent (SNP) | VAF 36/150 reads (24%) | catalogued as rs768198029, COSV52739139; called by muse, mutect2, varscan2
- PAPPA2 | c.3117G>A p.Q1039= | Silent (SNP) | VAF 32/169 reads (19%) | catalogued as COSV62790531; called by muse, mutect2, varscan2
- PCDH10 | c.477C>T p.Y159= | Silent (SNP) | VAF 32/77 reads (42%) | catalogued as rs1017775396, COSV52087497; called by muse, mutect2, varscan2
- PCDHA12 | c.2016C>T p.N672= | Silent (SNP) | VAF 34/79 reads (43%) | catalogued as rs781785108, COSV56477226; called by muse, mutect2, varscan2
- PLD1 | c.15C>T p.N5= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as rs145738077; called by muse, mutect2, varscan2
- PPP5C | c.357C>T p.Y119= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs987784830, COSV50139191; called by muse, mutect2, varscan2
- PRPF40A | c.273C>A p.L91= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as COSV58442028, COSV58444636; called by muse, mutect2, varscan2
- PXDN | c.3633C>T p.I1211= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs565581245, COSV53226499; ClinVar: likely benign; called by muse, mutect2, varscan2
- RHCE | c.963G>A p.G321= | Silent (SNP) | VAF 32/127 reads (25%) | catalogued as CD056850, COSV53798388; called by muse, mutect2, varscan2
- SBNO1 | c.1938C>T p.G646= (on ENST00000420886; = p.G645= on NM_018183.5) | Silent (SNP) | VAF 104/170 reads (61%) | catalogued as rs1375504738, COSV57338839, COSV57344304; called by muse, mutect2, varscan2
- SGK2 | c.555G>A p.L185= | Silent (SNP) | VAF 21/127 reads (17%) | catalogued as COSV58312075; called by muse, mutect2, varscan2
- SLC2A13 | c.1353C>T p.C451= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs1489754601, COSV55110933; called by muse, mutect2, varscan2
- SPAG1 | c.2316A>C p.A772= | Silent (SNP) | VAF 27/67 reads (40%) | catalogued as rs779086994, COSV52557831; called by muse, mutect2, varscan2
- SPTA1 | c.226T>C p.L76= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as COSV63748768, COSV63754867; called by muse, mutect2, varscan2
- SYNGR4 | c.411C>T p.L137= | Silent (SNP) | VAF 24/110 reads (22%) | catalogued as COSV61225065; called by muse, mutect2, varscan2
- TF | c.1782G>A p.A594= | Silent (SNP) | VAF 50/185 reads (27%) | catalogued as rs778400078, COSV53917621; called by muse, mutect2, varscan2
- TIAM1 | c.1260G>A p.P420= | Silent (SNP) | VAF 57/95 reads (60%) | catalogued as COSV54537380, COSV54554184; called by muse, mutect2, varscan2
- TMEM266 | c.747G>A p.T249= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as rs775930403, COSV66378514; called by muse, mutect2, varscan2
- TTN | c.41214A>G p.K13738= (on ENST00000591111; = p.K6314= on NM_003319.4) | Silent (SNP) | VAF 29/84 reads (35%) | catalogued as COSV59883991; called by muse, mutect2, varscan2
- VGLL3 | c.951A>G p.Q317= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV68207026; called by muse, mutect2, varscan2
- WDR93 | c.681G>A p.K227= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as COSV51530434; called by muse, mutect2, varscan2
- NACA | c.70+3018G>C | Intron (SNP) | VAF 17/39 reads (44%) | catalogued as COSV100771167; called by muse, mutect2, varscan2
